Surgical pathology report (de-identified scan), TCGA case TCGA-AT-A5NU, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site St. Joseph's Medical Center-(MD), specimen TCGA-AT-A5NU-01A (Primary Tumor).

[page 1 of 3]
Specimen Inquiry

ACCT #:

STATUS:

DOB:

AGE/SX: [REDACTED]

Flags: *H *L = Critical H,L = Abnormal #=Delta ** = Alpha Abn * Mic Abn

STATUS:

SUBM DR:

ORDERED: 88309, 88342/2, LEVEL VI - GROS, IMMUNOPEROXIDAS/2

SURGICAL PROCEDURES:

NEPHRECTOMY

GROSS DESCRIPTION

The specimen is submitted fresh as "left kidney" and consists of a kidney removed with attached adrenal gland and segment of ureter. The specimen has an overall dimension of 20 x 13 x 5 cm and a weight of 567 grams. The isolated kidney measures 12.5 x 5.5 x 5 cm. The capsule is removed with ease revealing a pink tan granular surface interrupted by a 4 x 3 x 2.5 cm serous cyst at the upper pole. There are two ligated vessels at the hilum ranging in length from 0.7 to 1.5 cm in length and measuring 0.6 and 0.4 cm in diameter respectively. The segment of attached ureter measures 7 cm in length and 0.3 cm in diameter at the margin of resection. The ureter and pelvis are red tan and glistening. Upon opening, the ureteral mucosa is pink tan with the usual striations. The pelvic mucosa is pink tan and unremarkable. Adjacent to the capsular cyst at the lower portion of the upper is a moderately firm red-yellow, focally hemorrhagic, relatively circumscribed tumor measuring 2 x 2.7 x 2.2 cm which extends to the rim of the cortex and protrudes into the surrounding perirenal fat. The tumor does not grossly invade the subjacent pelvis. The remaining renal parenchyma is pink tan and unremarkable. The cortex measures 0.8 cm in maximum thickness.

The attached adrenal gland measures 7 x 2 x 1.5 cm and weighs 7 grams. There is no gross involvement by tumor. Examination of the attached perirenal fat is unremarkable. No grossly apparent nodes are seen. Representative sections are submitted, multiple (12) labeled as follows:

Cassette 1:	Ureter and vessel margins
Cassettes 2-6:	Entirely submitted tumor (capsular margin black dye)
Cassettes 7-9:	Representative adjacent subcapsular cyst
Cassettes 10-11:	Representative uninvolved renal parenchyma
Cassette 12:	Representative adrenal gland

Please note: Gross photos have been taken. A portion of tissue is submitted for TCGA studies.

Patient: [REDACTED]

Age/Sex: [REDACTED]

Acct# [REDACTED]

Unit# [REDACTED]

ICD-0-3

Carcinoma, papillary renal cell

Site ④ Kidney NOS

8260/3

C64.9

[page 2 of 3]
Specimen Inquiry

Patient: [REDACTED]

ACCT#: [REDACTED]

(Continued)

FINAL DIAGNOSIS

LEFT KIDNEY, PROXIMAL URETER, PERINEPHRIC SOFT TISSUE, AND ADRENAL GLAND (RADICAL NEPHRECTOMY SPECIMEN): PAPILLARY RENAL CELL CARCINOMA, FUHRMAN NUCLEAR GRADE 2, 2.7 CM MAXIMUM DIAMETER, ARISING IN LOWER PORTION OF UPPER POLE. THE TUMOR DISTENDS, BUT DOES NOT PENETRATE, THE RENAL CAPSULE. ADJACENT 4 CM CORTICAL CYST ALSO NOTED. REMAINING KIDNEY SHOWS SCATTERED FOCI OF INTERSTITIAL CHRONIC INFLAMMATION AND MILD ARTERIOLOSCLEROSIS. VASCULAR AND URETERAL MARGINS AND ADRENAL GLAND ARE FREE OF DISEASE.

COMMENT: THE LESION IS OF PAPILLARY TYPE THROUGHOUT. IMMUNOPEROXIDASE STAINS WERE PERFORMED, AND THE LESION IS POSITIVE FOR RCC ANTIGEN BUT NEGATIVE FOR TTF-1, CONFIRMING THE RENAL ORIGIN.

Unless otherwise specified, the performance characteristics of the immunoperoxidase stains performed here have been confirmed by the [REDACTED] These tests have not been cleared or approved by the U.S. Food and Drug Administration, although such approval is not necessary.

SYNOPTIC REPORT

SYNOPTIC REPORT: KIDNEY
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: RADICAL NEPHRECTOMY

LATERALITY: LEFT

TUMOR SITE: LOWER PORTION OF UPPER POLE

TUMOR FOCALITY: UNIFOCAL

TUMOR SIZE (LARGEST TUMOR, IF MULTIPLE): 2.7 CM

MACROSCOPIC EXTENT OF TUMOR: PROTRUDES INTO ADJACENT SOFT TISSUES

MICROSCOPIC EXTENT OF TUMOR: CAPSULAR DISTENTION, BUT STILL CONFINED
WITHIN KIDNEY

HISTOLOGIC TYPE: PAPILLARY

SARCOMATOID FEATURES (PRESENT/ABSENT): ABSENT

HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): 2

VENOUS (INCL. IVC) INVOLVEMENT (IF PRESENT, SPECIFY): ABSENT

ADRENAL INVOLVEMENT: ABSENT

MARGINS:

CAPSULAR, PARENCHYMAL (IF APPLICABLE): N/A

PERINEPHRIC FAT: UNINVOLVED

RENAL VEIN: UNINVOLVED

URETER: UNINVOLVED

Patient: [REDACTED]

Age/Sex: [REDACTED]

Acct# [REDACTED]

Unit# [REDACTED]

[page 3 of 3]
Patient: [REDACTED]

ACCT#: [REDACTED]

(Continued)

SYNOPTIC REPORT

(Continued)

LYMPH NODES:

INVOLVED/ # EXAMINED: N/A

PATHOLOGIC FINDINGS IN NON-NEOPLASTIC KIDNEY (SPECIFY): FOCAL INTERSTITIAL
CHRONIC INFLAMMATION. MILD ARTERIOLOSCLEROSIS.

OTHER PERTINENT FINDINGS: (SEE NARRATIVE)

PTNM STAGE: pT1a NX MX

Signed(Electronically) < SIGNATURE ON FILE >

PATHOLOGIST

Patient: [REDACTED]

Age/Sex: [REDACTED]

Acct# [REDACTED]

Unit: [REDACTED]

HPA Discrepancy		
Case is (Circ):		

Source: NCI Genomic Data Commons file 25037cc1-43fe-4abd-b29c-62d41a4eb7ec (TCGA-AT-A5NU.F9306089-8DC7-4B52-A61D-FCEF2A1D2AB7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).